Somatic mutation profile of tumor specimen MMRF_2174_1_BM_CD138pos (aliquot MMRF_2174_1_BM_CD138pos_T1_KHS5U_L08797) from MMRF case MMRF_2174, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.5 years (31,241 days).
Specimen MMRF_2174_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d31001eb-16a5-4ef4-bf23-f5acab9241e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2174_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2174_1_PB_Whole_C3_KHS5U_L08772; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f0ad26-7e0e-463c-a1ad-2afa371aee4b

The open-access MAF lists 73 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 17, Intron 8, Silent 7, 5'Flank 5, 5'UTR 2, 3'Flank 2, Splice Region 2, RNA 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772948778, COSV51673784, COSV51677393; called by muse, mutect2, varscan2
- ADGRE4P | n.2431G>A | Splice Region (SNP) | VAF 40/93 reads (43%) | catalogued as rs761125784; called by muse, mutect2, varscan2
- EIF5AL1 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs928720295, COSV73123170; called by muse, mutect2, varscan2
- FBF1 | c.1792C>T p.R598W (on ENST00000586717; = p.R612W on NM_001319193.1) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765962914, COSV59866097; called by muse, mutect2, varscan2
- HSPG2 | c.7976C>T p.A2659V | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.61); catalogued as rs1344945596; called by muse, mutect2, varscan2
- IGHV2-70 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs537351011; called by muse, varscan2
- IGKV3-20 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs190424065; called by muse, varscan2
- IGKV3-20 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.087); catalogued as rs535719804; called by muse, varscan2
- IGLV3-1 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs367971405; called by muse, mutect2, varscan2
- IQUB | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776984564, COSV61243119; called by muse, mutect2
- LRP1B | c.2734G>T p.G912W | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796637; called by muse, mutect2, varscan2
- NECTIN2 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs761668689; called by muse, mutect2, varscan2
- TMEM26 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527927252, COSV53263573; called by muse, mutect2, varscan2
- UPP1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs904263504; called by muse, mutect2
- CA12 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, varscan2
- EMILIN1 | c.2665T>G p.F889V | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM171A2 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- HCN1 | c.1824T>A p.D608E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KCNK1 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MED12 | c.203_204+3delinsC p.X68_splice | Splice Site (DEL) | VAF 18/20 reads (90%) | called by pindel, varscan2*
- NPAS3 | c.480del p.F161Lfs*5 (on ENST00000356141 / NM_001164749.2; = p.F129Lfs*5 on NM_022123.3) | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- NXPE1 | c.1635C>A p.Y545* (on ENST00000424269; = p.Y403* on NM_152315.5) | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- PNPLA8 | c.408A>C p.L136F | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); called by mutect2, varscan2
- PROM2 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SLC9B2 | c.1254A>C p.V418= | Splice Region (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- SOD3 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SYNE2 | c.9909G>T p.L3303F | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by mutect2, varscan2
- THAP11 | c.43T>G p.S15A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2
- TTC9B | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, varscan2
- ZNF777 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CACNA1C | c.162G>A p.A54= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as rs760297846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN10 | c.171A>G p.P57= | Silent (SNP) | VAF 52/108 reads (48%) | called by muse, varscan2
- CERS5 | c.549T>C p.L183= | Silent (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- CILP2 | c.2493C>T p.T831= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs760392757; called by muse, mutect2, varscan2
- IGLV4-3 | c.192G>A p.Q64= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs760596970; called by muse, mutect2, varscan2
- MRC1 | c.1611T>A p.A537= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- STK11 | c.282C>T p.N94= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- ABCC8 | c.3868-181G>A | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- ADCY6 | c.*1353C>T | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- ARMC8 | c.45+401G>A | Intron (SNP) | VAF 41/148 reads (28%) | catalogued as rs1202265990; called by muse, mutect2, varscan2
- BACE2 | chr21:41167884 C>T | 5'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- BDKRB2 | c.74+1440A>G | Intron (SNP) | VAF 74/170 reads (44%) | catalogued as rs1406348173; called by muse, mutect2, varscan2
- CD47 | c.*2891T>A | 3'UTR (SNP) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- CHCHD4 | chr3:14125038 del AG | 5'Flank (DEL) | VAF 48/162 reads (30%) | called by mutect2, varscan2
- CNNM1 | c.*1665G>A | 3'UTR (SNP) | VAF 53/127 reads (42%) | catalogued as rs1408441620; called by muse, mutect2, varscan2
- EFNB2 | c.*3201G>C | 3'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- GABRA6 | c.673+72T>A | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- GAPVD1 | chr9:125366090 G>A | 3'Flank (SNP) | VAF 39/41 reads (95%) | catalogued as rs764255277; called by muse, mutect2, varscan2
- GIMAP1 | c.*1483C>T | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1199T>A | RNA (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- ITGA3 | chr17:50056089 C>T | 5'Flank (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-45686G>A | Intron (SNP) | VAF 85/168 reads (51%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18866G>A | Intron (SNP) | VAF 22/38 reads (58%) | catalogued as rs1345217442; called by muse, mutect2, varscan2
- LUZP2 | c.*1487T>G | 3'UTR (SNP) | VAF 44/61 reads (72%) | called by muse, mutect2, varscan2
- MALT1 | c.1475+33C>T | Intron (SNP) | VAF 70/141 reads (50%) | catalogued as rs775122690; called by muse, mutect2, varscan2
- MGAM | c.*1A>G | 3'UTR (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2
- MYO1E | c.-49T>C | 5'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- NAB1 | c.*981C>T | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*1238A>G | 3'UTR (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- ORMDL1 | chr2:189770297 T>C | 3'Flank (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2
- PEAK1 | c.*313T>C | 3'UTR (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- PIGR | c.-49G>T | 5'UTR (SNP) | VAF 62/189 reads (33%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1372-85698C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs961592917; called by muse, varscan2
- SLC35G1 | c.*1287C>A | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- SNX16 | c.*670T>C | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- SORL1 | c.*1803_*1805delinsTTTTTAAGT | 3'UTR (INS) | VAF 12/60 reads (20%) | catalogued as COSV52759552; called by pindel, varscan2*
- TAS2R7 | c.*60T>C | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.450C>T | RNA (SNP) | VAF 44/85 reads (52%) | catalogued as rs201495764; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975388 T>C | 5'Flank (SNP) | VAF 39/39 reads (100%) | catalogued as rs971184875; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975518 C>T | 5'Flank (SNP) | VAF 77/80 reads (96%) | catalogued as rs777371590, COSV104432402, COSV66081085; called by muse, varscan2
- TRAM2 | c.*337G>T | 3'UTR (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- TTC19 | c.*526T>C | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- ZFP64 | c.*805del | 3'UTR (DEL) | VAF 17/37 reads (46%) | catalogued as rs753497165; called by mutect2, pindel, varscan2
